Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9D0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9D0-01A (Primary Tumor).

[page 1 of 13]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Edited

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #

Specimen:

Date of Procedure:

Performing Clinician:

- A. Central liver resection with gallbladder
- B. Biopsy L lateral segment FS
- C. Perigastric lymph node
- D. Midbody stomach resection

Clinical Notes:

Liver mass. Specimen A: Fresh tissue saved for
tissue bank.

Diagnosis:

REVISED REPORT

- A. Central liver resection with gallbladder:
- Well differentiated hepatocellular carcinoma.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.
- B. Biopsy left lateral segment:
- Mild steatosis, negative for malignancy.
- C. Perigastric lymph node:
- Negative for tumor.
- D. Midbody stomach resection:
- Benign gastrointestinal stromal tumor.
- No mitosis identified.

ICD O-3

Carcinoma, hepatocellular
NOS 8170/3

Site Liver CA20

J 2/13/14

REVISED REPORT COMMENT: CHANGE IN DIAGNOSIS. This report is revised to change the diagnosis for specimen B from "Well differentiated hepatocellular carcinoma. AJCC Stage: pT1, NX, MX. Please see Tumor Characteristics" to "Mild steatosis, negative for malignancy" (underlined above). Also, the microscopic description is changed (see below). These results were communicated via telephone to
None of the other original text has

[page 2 of 13]
[REDACTED]

been altered.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed and its performance characteristics determined by [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not

Accession #:

necessary. By placing the electronic signature on this report, the pathologist certifies that all positive and negative immunohistochemistry controls were reviewed and approved.

(Electronically signed by)
Verified:

Tumor Characteristics:
A: Liver, Resection (AJCC 7th Ed., 2010)
SPECIMEN TYPE:
Central liver resection
FOCALITY:
Solitary (specify location): Central part
TUMOR SIZE:
Greatest dimension: 14 cm
Additional dimensions: 9 cm
HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GI: Well differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM)
AJCC STAGING (pTNM):
pT1, NX, MX
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 2.5 mm
Bile duct margin cannot be assessed
LYMPH-VASCULAR INVASION:
Macroscopic Venous (Large Vessel) Invasion
Not identified
Microscopic (Small Vessel) Invasion
Not identified

[page 3 of 13]
Gross:

A. The specimen is labeled "central liver resection and gallbladder." Received in _____ and transferred to formalin is a 513 gram, 15.0 x 17.0 x 10.0 cm, portion of liver with attached gallbladder, approximately 5.0 x 2.0 x 1.0 cm. The liver capsule is red-purple and was previously inked in black over the surgical margin. The specimen is

Accession #:

serially sectioned. On sectioning, it reveals a 14.0 x 9.0 cm well-circumscribed, tan-yellow mass with a necrotic center, about 2.5 x 4.0 cm. The mass is about 2.5 cm away from the inked margin. The remainder of the liver parenchyma is dark brown. Representative sections are submitted as follows:

Cassette Designation:

A1	Section from the mass
A2	Section from the mass plus the adjacent unremarkable tissue
A3	Section from the necrotic area of the mass
A4	Mass plus adjacent unremarkable tissue
A5	Representative sections from the unremarkable liver
A6	Section from the mass plus necrotic center
A7	Mass near the inked margin

The gallbladder has a yellow-tan serosal surface. There is a disrupted area, about 1.0 x 1.0 cm, over the serosal surface. The gallbladder is opened and it has a tan-yellow, smooth mucosa, with scattered yellow spots. Representative sections, including the cystic duct margin, are submitted in cassette A8.

B. The specimen is labeled "biopsy, left lateral segment." Received fresh for frozen section are two tan-yellow cores of liver, about 1.5 cm in greatest dimension, and the specimen is submitted in toto for frozen section. The frozen section remnant is submitted for permanent in cassette B.

C. The specimen is labeled "perigastric lymph node." Received in formalin is a 1.5 x 1.1 x 0.3 cm tan-yellow lymph node. The specimen is bisected and submitted entirely in cassette C.

[page 4 of 13]
[REDACTED]

D. The specimen is labeled "midbody stomach resection." Received in formalin is a 3.0 x 2.0 x 0.5 cm fragment of pink-tan soft tissue. The specimen is inked in black over the deep surface and serially sectioned. On sectioning, it was a 0.3 x 0.3 x 0.4 cm tan-white lesion which is about 0.2 cm away from the inked margin. The specimen is submitted entirely in cassettes D1 to D3.

Accession #:

Intraoperative Consultation:
FROZEN SECTION:
B. Not diagnostic

Microscopic:
Histological examinations have been performed on specimens A-D.

A. Sections show well-circumscribed mass composed of nests of cells with large, hyperchromatic nuclei. There is an evidence of massive necrosis in the central part of the mass. Normal portal triad architecture is not identified in most parts of the mass. There is no evidence of margin, vascular involvement. Sections from the gallbladder show unremarkable columnar mucosa with normal wall thickness and there is no evidence of tumor extension into the gallbladder. Glypican stain shows patchy positivity and reticuline shows multiple areas of disruption which confirm the diagnosis.

B. H and E, trichrome, and reticulin-stained sections demonstrate cores of liver tissue with hepatocytes arranged in cell layers one cell thick. The lobular architecture is intact with no fibrosis. Mild macrovesicular steatosis is present that comprises less than 10% of the specimen volume. Negative for lobular necroinflammatory activity. Negative for dysplasia or malignancy.

C. Sections show two fragments of lymphoid tissue. There is no evidence of tumor inside the lymph node.

D. Sections show a well-circumscribed mass composed of

[REDACTED]

[page 5 of 13]
[REDACTED]

nests of spindle cells with short, uniform nuclei. The cells form whorled, storiform patterns and are separated by fibrovascular septae. There is no evidence of margin involvement. The gastric mucosa is unremarkable. CD117, SMA, DOG-1 immunohistochemistry stains are performed on block D2 and the results are as follows:
Dog-1, CD117 are strongly positive and SMA is negative.

Accession #:

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time	Lab Status Final result	Entered by
---------------------	----------------------------	------------

Component Results

Component SURG PATH FINAL REPORT
--

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

- A. Central liver resection with gallbladder
- B. Biopsy L lateral segment FS
- C. Perigastric lymph node
- D. Midbody stomach resection

Clinical Notes:

Liver mass. Specimen A: Fresh tissue saved for

[REDACTED]

[page 6 of 13]
[REDACTED]

tissue bank.

Diagnosis:

- A. Central liver resection with gallbladder:
- Well differentiated hepatocellular carcinoma.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.
- B. Biopsy left lateral segment:
- Well differentiated hepatocellular carcinoma.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.
- C. Perigastric lymph node:
- Negative for tumor.
- D. Midbody stomach resection:
- Benign gastrointestinal stromal tumor.
- No mitosis identified.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. By placing the electronic signature on this report, the pathologist certifies that all positive and negative immunohistochemistry controls were reviewed and approved.

(Electronically signed by)

Accession #:

Tumor Characteristics:

A: Liver, Resection (AJCC 7th Ed., 2010)

SPECIMEN TYPE:

Central liver resection

FOCALITY:

Solitary (specify location): Central part

TUMOR SIZE:

Greatest dimension: 14 cm

Additional dimensions: 9 cm

HISTOLOGIC TYPE:

Hepatocellular carcinoma

[REDACTED]

[page 7 of 13]
[REDACTED]

HISTOLOGIC GRADE:
GI: Well differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM)
AJCC STAGING (pTNM):
pT1, NX, MX
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 2.5
mm
Bile duct margin cannot be assessed
LYMPH-VASCULAR INVASION:
Macroscopic Venous (Large Vessel) Invasion
Not identified
Microscopic (Small Vessel) Invasion
Not identified

Gross:

A. The specimen is labeled "central liver resection and gallbladder." Received in Tis-U-Sol and transferred to formalin is a 513 gram, 15.0 x 17.0 x 10.0 cm, portion of liver with attached gallbladder, approximately 5.0 x 2.0 x 1.0 cm. The liver capsule is red-purple and was previously inked in black over the surgical margin. The specimen is serially sectioned. On sectioning, it reveals a 14.0 x 9.0 cm well-circumscribed, tan-yellow mass with a necrotic center, about 2.5 x 4.0 cm. The mass is about 2.5 cm away from the inked margin. The remainder of the liver parenchyma is dark brown. Representative sections are submitted as follows:

Cassette Designation:

A1	Section from the mass
----	-----------------------

Accession #:

A2	Section from the mass plus the adjacent unremarkable tissue
A3	Section from the necrotic area of the mass
A4	Mass plus adjacent unremarkable tissue
A5	Representative sections from the unremarkable liver
A6	Section from the mass plus necrotic center
A7	Mass near the inked margin

[page 8 of 13]
[REDACTED]

The gallbladder has a yellow-tan serosal surface. There is a disrupted area, about 1.0 x 1.0 cm, over the serosal surface. The gallbladder is opened and it has a tan-yellow, smooth mucosa, with scattered yellow spots. Representative sections, including the cystic duct margin, are submitted in cassette A8.

B. The specimen is labeled "biopsy, left lateral segment." Received fresh for frozen section are two tan-yellow cores of liver, about 1.5 cm in greatest dimension, and the specimen is submitted in toto for frozen section. The frozen section remnant is submitted for permanent in cassette B.

C. The specimen is labeled "perigastric lymph node." Received in formalin is a 1.5 x 1.1 x 0.3 cm tan-yellow lymph node. The specimen is bisected and submitted entirely in cassette C.

D. The specimen is labeled "midbody stomach resection." Received in formalin is a 3.0 x 2.0 x 0.5 cm fragment of pink-tan soft tissue. The specimen is inked in black over the deep surface and serially sectioned. On sectioning, it was a 0.3 x 0.3 x 0.4 cm tan-white lesion which is about 0.2 cm away from the inked margin. The specimen is submitted entirely in cassettes D1 to D3.

Intraoperative Consultation:

FROZEN SECTION:

B. Not diagnostic

Accession #:

Microscopic:

Histological examinations have been performed on specimens A-D.

A. Sections show well-circumscribed mass composed of nests of cells with large, hyperchromatic nuclei. There is an evidence of massive necrosis in the central part of the mass. Normal portal triad architecture is not identified in most parts of the mass. There is no evidence of margin,

[page 9 of 13]
[REDACTED]

vascular involvement. Sections from the gallbladder show unremarkable columnar mucosa with normal wall thickness and there is no evidence of tumor extension into the gallbladder. Glypican stain shows patchy positivity and reticuline shows multiple areas of disruption which confirm the diagnosis.

B. Sections show fragments of liver tissue composed of cells with large nuclei. Mild steatosis (less than 10%) is identified.

C. Sections show two fragments of lymphoid tissue. There is no evidence of tumor inside the lymph node.

D. Sections show a well-circumscribed mass composed of nests of spindle cells with short, uniform nuclei. The cells form whorled, storiform patterns and are separated by fibrovascular septae. There is no evidence of margin involvement. The gastric mucosa is unremarkable. CD117, SMA, DOG-1 immunohistochemistry stains are performed on block D2 and the results are as follows:
Dog-1, CD117 are strongly positive and SMA is negative.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time	Lab Status Final result	Entered by
---------------------	----------------------------	------------

Component Results

Component SURG PATH FINAL REPORT
--

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

- A. Central liver resection with gallbladder
- B. Biopsy L lateral segment FS
- C. Perigastric lymph node
- D. Midbody stomach resection

Clinical Notes:

[REDACTED]

[page 10 of 13]
[REDACTED]

Liver mass. Specimen A: Fresh tissue saved for
tissue bank.

Diagnosis:

- A. Central liver resection with gallbladder:
- Well differentiated hepatocellular carcinoma.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.
- B. Biopsy left lateral segment:
- Well differentiated hepatocellular carcinoma.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.
- C. Perigastric lymph node:
- Negative for tumor.
- D. Midbody stomach resection:
- Benign gastrointestinal stromal tumor.
- No mitosis identified.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed
and its performance characteristics determined by

It has not been cleared or
approved by the U.S. Food and Drug Administration. The FDA
has determined that such clearance or approval is not
necessary. By placing the electronic signature on this
report, the pathologist certifies that all positive and
negative immunohistochemistry controls were reviewed and
approved.

(Electronically signed by)
Verified:

Accession #:

Tumor Characteristics:

A: Liver, Resection (AJCC 7th Ed., 2010)

SPECIMEN TYPE:

Central liver resection

FOCALITY:

Solitary (specify location): Central part

TUMOR SIZE:

Greatest dimension: 14 cm

Additional dimensions: 9 cm

HISTOLOGIC TYPE:

[REDACTED]

[page 11 of 13]
[REDACTED]

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GI: Well differentiated

PRIMARY TUMOR (pT):

pT1: Solitary tumor without vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM)

AJCC STAGING (pTNM):

pT1, NX, MX

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 2.5

mm

Bile duct margin cannot be assessed

LYMPH-VASCULAR INVASION:

Macroscopic Venous (Large Vessel) Invasion

Not identified

Microscopic (Small Vessel) Invasion

Not identified

Gross:

A. The specimen is labeled "central liver resection and gallbladder." Received in [REDACTED] and transferred to formalin is a 513 gram, 15.0 x 17.0 x 10.0 cm, portion of liver with attached gallbladder, approximately 5.0 x 2.0 x 1.0 cm. The liver capsule is red-purple and was previously inked in black over the surgical margin. The specimen is serially sectioned. On sectioning, it reveals a 14.0 x 9.0 cm well-circumscribed, tan-yellow mass with a necrotic center, about 2.5 x 4.0 cm. The mass is about 2.5 cm away from the inked margin. The remainder of the liver parenchyma is dark brown. Representative sections are submitted as follows:

Cassette Designation:

A1

Section from the mass

Accession #:

A2

Section from the mass plus the adjacent unremarkable tissue

A3

Section from the necrotic area of the mass

A4

Mass plus adjacent unremarkable tissue

A5

Representative sections from the unremarkable liver

A6

Section from the mass plus necrotic center

[page 12 of 13]
[REDACTED]

A7

Mass near the inked margin

The gallbladder has a yellow-tan serosal surface. There is a disrupted area, about 1.0 x 1.0 cm, over the serosal surface. The gallbladder is opened and it has a tan-yellow, smooth mucosa, with scattered yellow spots. Representative sections, including the cystic duct margin, are submitted in cassette A8.

B. The specimen is labeled "biopsy, left lateral segment." Received fresh for frozen section are two tan-yellow cores of liver, about 1.5 cm in greatest dimension, and the specimen is submitted in toto for frozen section. The frozen section remnant is submitted for permanent in cassette B.

C. The specimen is labeled "perigastric lymph node." Received in formalin is a 1.5 x 1.1 x 0.3 cm tan-yellow lymph node. The specimen is bisected and submitted entirely in cassette C.

D. The specimen is labeled "midbody stomach resection." Received in formalin is a 3.0 x 2.0 x 0.5 cm fragment of pink-tan soft tissue. The specimen is inked in black over the deep surface and serially sectioned. On sectioning, it was a 0.3 x 0.3 x 0.4 cm tan-white lesion which is about 0.2 cm away from the inked margin. The specimen is submitted entirely in cassettes D1 to D3.

Intraoperative Consultation:

FROZEN SECTION:

B. Not diagnostic

Accession #:

Microscopic:

Histological examinations have been performed on specimens A-D.

A. Sections show well-circumscribed mass composed of nests of cells with large, hyperchromatic nuclei. There is an evidence of massive necrosis in the central part of the mass. Normal portal triad architecture is not identified in

[page 13 of 13]
[REDACTED]

most parts of the mass. There is no evidence of margin, vascular involvement. Sections from the gallbladder show unremarkable columnar mucosa with normal wall thickness and there is no evidence of tumor extension into the gallbladder. Glypican stain shows patchy positivity and reticuline shows multiple areas of disruption which confirm the diagnosis.

B. Sections show fragments of liver tissue composed of cells with large nuclei. Mild steatosis (less than 10%) is identified.

C. Sections show two fragments of lymphoid tissue. There is no evidence of tumor inside the lymph node.

D. Sections show a well-circumscribed mass composed of nests of spindle cells with short, uniform nuclei. The cells form whorled, storiform patterns and are separated by fibrovascular septae. There is no evidence of margin involvement. The gastric mucosa is unremarkable. CD117, SMA, DOG-1 immunohistochemistry stains are performed on block D2 and the results are as follows:
Dog-1, CD117 are strongly positive and SMA is negative.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

[REDACTED]

Source: NCI Genomic Data Commons file b4483c15-580b-42d3-8eaa-77f98a7e5275 (TCGA-ZP-A9D0.38325470-AA90-4CA4-A8C0-8BF1A9D595F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).